Somatic mutation profile of tumor specimen C3N-03072-01 (aliquot CPT0209020007) from CPTAC case C3N-03072, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.0 years (22,994 days).
Specimen C3N-03072-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2a841e1-4516-424d-b90c-2473aa0c41b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03072-31 (Blood Derived Normal), aliquot CPT0209080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e93d466-23e5-4aef-bdb5-24776ed42367

The open-access MAF lists 288 somatic variants for this specimen: 184 protein-altering or splice-affecting, 68 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 148, Silent 68, Nonsense Mutation 15, Intron 14, RNA 10, Frame Shift Del 8, Splice Region 5, 5'UTR 5, 3'UTR 5, Splice Site 4, Frame Shift Ins 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.811G>T p.E271* | Nonsense Mutation (SNP) | VAF 282/586 reads (48%) | hotspot (GDC flag); catalogued as COSV52666332, COSV52700326, COSV52746468; called by muse, mutect2, varscan2
- AFM | c.747G>T p.K249N | Missense Mutation (SNP) | VAF 65/129 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56919038; called by muse, mutect2
- ANKRD65 | c.413G>C p.G138A | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs912817271; called by muse, mutect2, varscan2
- AP2M1 | c.368A>T p.N123I | Missense Mutation (SNP) | VAF 372/737 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.288); catalogued as COSV53048710; called by muse, mutect2, varscan2
- APOB | c.3118G>A p.E1040K | Missense Mutation (SNP) | VAF 194/624 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.879); catalogued as COSV51941714; called by muse, mutect2, varscan2
- ARHGAP30 | c.2347T>C p.W783R | Missense Mutation (SNP) | VAF 110/326 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1374865088; called by muse, mutect2, varscan2
- ASPM | c.8227C>G p.R2743G | Missense Mutation (SNP) | VAF 135/356 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as CM1415104, COSV99659160; called by muse, mutect2, varscan2
- ATP12A | c.3026C>T p.P1009L | Missense Mutation (SNP) | VAF 254/381 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs112835811; called by muse, mutect2, varscan2
- BEGAIN | c.1048G>C p.A350P | Missense Mutation (SNP) | VAF 67/374 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs760231970; called by muse, mutect2, varscan2
- CADPS | c.550T>C p.Y184H | Missense Mutation (SNP) | VAF 70/116 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as rs1304651123; called by muse, mutect2, varscan2
- CFH | c.1903G>T p.E635* | Nonsense Mutation (SNP) | VAF 70/259 reads (27%) | catalogued as COSV66409862; called by muse, mutect2, varscan2
- CHD9 | c.310C>G p.P104A | Missense Mutation (SNP) | VAF 80/185 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs763090133; called by muse, mutect2, varscan2
- CIART | c.82T>G p.F28V | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.087); catalogued as rs782602205; called by muse, mutect2, varscan2
- COL9A1 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 93/463 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs924701727; called by muse, mutect2, varscan2
- CSMD3 | c.8346C>G p.I2782M (on ENST00000297405 / NM_001363185.1; = p.I2613M on NM_052900.3) | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV52108121; called by muse, mutect2, varscan2
- DAB2 | c.2005C>T p.R669W | Missense Mutation (SNP) | VAF 235/759 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200943679; called by muse, mutect2, varscan2
- DACH1 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 81/147 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57507167, COSV57509798; called by muse, mutect2, varscan2
- DSP | c.2645A>C p.E882A | Missense Mutation (SNP) | VAF 171/303 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV65794533; called by muse, mutect2, varscan2
- F11 | c.1537G>T p.D513Y | Missense Mutation (SNP) | VAF 101/221 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); catalogued as COSV99250711; called by muse, mutect2, varscan2
- FAM131A | c.467C>A p.S156* (on ENST00000310585; = p.S187* on NM_144635.5) | Nonsense Mutation (SNP) | VAF 34/333 reads (10%) | catalogued as COSV55600985; called by muse, mutect2, varscan2
- FAM135B | c.1642G>C p.A548P | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV52728853, COSV99425888; called by muse, mutect2
- FGD3 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 22/254 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV61598778; called by muse, mutect2
- GABRG3 | c.38C>G p.S13W | Missense Mutation (SNP) | VAF 38/358 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as COSV61518171; called by muse, mutect2, varscan2
- GCC1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 86/492 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs372138184; called by muse, mutect2, varscan2
- GGNBP2 | c.74A>G p.Y25C | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as rs575661510; called by muse, mutect2, varscan2
- GPC5 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs145336505; called by muse, mutect2, varscan2
- HEPHL1 | c.616G>T p.V206F | Missense Mutation (SNP) | VAF 131/317 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); catalogued as COSV59889948; called by muse, mutect2, varscan2
- HIC2 | c.656G>T p.C219F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.347); catalogued as COSV68042595; called by muse, mutect2, varscan2
- IFT172 | c.535T>G p.Y179D | Missense Mutation (SNP) | VAF 51/201 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99562541; called by muse, mutect2, varscan2
- KCNMB2 | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 54/540 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs1207390700; called by muse, mutect2, varscan2
- KEAP1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50263607, COSV50635893; called by muse, mutect2, varscan2
- KRT8 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as rs1452905164; called by muse, mutect2, varscan2
- LCE2B | c.226C>A p.H76N | Missense Mutation (SNP) | VAF 85/697 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen probably damaging (0.969); catalogued as COSV64227722; called by muse, mutect2, varscan2
- LILRA5 | c.878C>T p.P293L | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100006662; called by muse, mutect2, varscan2
- MYEF2 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 116/708 reads (16%) | catalogued as COSV51048186; called by muse, mutect2, varscan2
- MYLPF | c.434C>A p.P145H | Missense Mutation (SNP) | VAF 58/252 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.546); catalogued as rs369244674; called by muse, mutect2, varscan2
- MYO6 | c.2037C>G p.H679Q | Missense Mutation (SNP) | VAF 188/510 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1175676949; called by muse, mutect2, varscan2
- MYOD1 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 71/496 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV51452513; called by muse, mutect2, varscan2
- NLRC5 | c.4847A>G p.N1616S | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1199877688; called by muse, mutect2, varscan2
- NOTCH2 | c.6396G>C p.K2132N | Missense Mutation (SNP) | VAF 253/502 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); catalogued as COSV56683795; called by muse, mutect2, varscan2
- OR4Q2 | c.303A>T p.Q101H | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as rs766388198; called by muse, mutect2, varscan2
- OR5D13 | c.506C>A p.S169* | Nonsense Mutation (SNP) | VAF 44/259 reads (17%) | catalogued as rs755031247, COSV62332993; called by muse, mutect2, varscan2
- PDZRN4 | c.2711G>C p.R904T (on ENST00000402685 / NM_001164595.2; = p.R646T on NM_013377.4) | Missense Mutation (SNP) | VAF 104/267 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100113549; called by muse, mutect2, varscan2
- PFKFB2 | c.1051C>T p.R351* | Nonsense Mutation (SNP) | VAF 58/161 reads (36%) | catalogued as rs779065776, COSV65547735; called by muse, mutect2, varscan2
- PLEC | c.8078G>A p.R2693Q (on ENST00000322810 / NM_201380.4; = p.R2583Q on NM_000445.5) | Missense Mutation (SNP) | VAF 225/1616 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs782640329, COSV100511219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PMP22 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 225/436 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773478255; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POTEH | c.50del p.P17Hfs*38 | Frame Shift Del (DEL) | VAF 203/1460 reads (14%) | catalogued as COSV58885710, COSV58887834; called by pindel, varscan2
- PRPH | c.1217+3G>A | Splice Region (SNP) | VAF 133/422 reads (32%) | catalogued as rs1257550017; called by muse, mutect2, varscan2
- PRR19 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 61/479 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as rs143542522; called by muse, mutect2, varscan2
- RSPH9 | c.534G>T p.L178F | Missense Mutation (SNP) | VAF 117/796 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.043); catalogued as rs1305418368, COSV64665658; called by muse, mutect2, varscan2
- SCN1A | c.3724_3725dup p.D1243Lfs*28 (on ENST00000303395 / NM_001202435.3; = p.D1232Lfs*28 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 53/171 reads (31%) | catalogued as rs796053072; called by mutect2, varscan2
- SFMBT2 | c.611G>A p.W204* | Nonsense Mutation (SNP) | VAF 115/255 reads (45%) | catalogued as rs774257979; called by muse, mutect2, varscan2
- SLC6A13 | c.338-4G>T | Splice Region (SNP) | VAF 109/265 reads (41%) | catalogued as rs780217461; called by muse, mutect2, varscan2
- THSD7A | c.4365T>G p.N1455K | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1265465260; called by muse, mutect2, varscan2
- TIMD4 | c.648G>C p.E216D | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.665); catalogued as COSV50857140; called by muse, mutect2, varscan2
- TMEM259 | c.1403C>G p.P468R | Missense Mutation (SNP) | VAF 189/429 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.334); catalogued as COSV99312758; called by muse, mutect2, varscan2
- TMEM59L | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 99/250 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs552926534; called by muse, mutect2, varscan2
- TSC2 | c.3364C>T p.R1122C | Missense Mutation (SNP) | VAF 122/351 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs397514938, CD1513758, COSV54774961; ClinVar: not provided / uncertain significance / benign; called by muse, mutect2, varscan2
- VPS51 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 111/554 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1308524421, COSV54207649; called by muse, mutect2, varscan2
- VPS51 | c.557G>T p.R186L | Missense Mutation (SNP) | VAF 112/555 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99074057; called by muse, mutect2, varscan2
- WDR35 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 58/416 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs375062321; called by muse, mutect2, varscan2
- WNK2 | c.4734G>C p.R1578S (on ENST00000297954 / NM_001282394.1; = p.R1541S on NM_006648.3) | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52944357; called by muse, mutect2
- ZBBX | c.90G>A p.M30I | Missense Mutation (SNP) | VAF 99/472 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as rs867318632; called by muse, mutect2, varscan2
- ZNF530 | c.1159G>T p.A387S | Missense Mutation (SNP) | VAF 44/291 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV60532038; called by muse, mutect2, varscan2
- ZNF853 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 140/465 reads (30%) | catalogued as rs1341825042; called by muse, mutect2, varscan2
- ZNHIT1 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs758030402, COSV59312572; called by muse, mutect2, varscan2
- ABCC9 | c.2630C>G p.T877R | Missense Mutation (SNP) | VAF 28/419 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.07); called by muse, mutect2
- ADGB | c.3842T>G p.L1281* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- AHCTF1 | c.586G>C p.D196H (on ENST00000366508; = p.D170H on NM_015446.5) | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- AIM2 | c.193A>T p.T65S | Missense Mutation (SNP) | VAF 125/460 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ANKRD30B | c.531A>T p.L177F | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- APBB2 | c.594del p.T199Pfs*25 | Frame Shift Del (DEL) | VAF 70/324 reads (22%) | called by mutect2, pindel, varscan2
- APH1A | c.734G>A p.C245Y | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARHGAP20 | c.504-2A>T p.X168_splice | Splice Site (SNP) | VAF 19/170 reads (11%) | called by muse, mutect2, varscan2
- ATAD3A | c.1418T>A p.I473K | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ATP13A4 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 169/852 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- ATP1A4 | c.338G>A p.W113* | Nonsense Mutation (SNP) | VAF 195/603 reads (32%) | called by muse, mutect2, varscan2
- AVEN | c.1058T>A p.L353Q | Missense Mutation (SNP) | VAF 82/281 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BARHL1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 169/747 reads (23%) | called by muse, mutect2, varscan2
- BARX1 | c.649C>A p.P217T | Missense Mutation (SNP) | VAF 52/389 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCKDK | c.426C>G p.I142M | Missense Mutation (SNP) | VAF 93/292 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- BNC1 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 154/373 reads (41%) | called by muse, mutect2, varscan2
- BTG2 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 259/572 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- C1orf112 | c.-23A>C | Splice Region (SNP) | VAF 41/95 reads (43%) | called by muse, mutect2, varscan2
- C8orf48 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- CACNA1C | c.2818T>C p.F940L | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CARMIL1 | c.1465A>G p.I489V | Missense Mutation (SNP) | VAF 145/238 reads (61%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCDC168 | c.12850A>G p.T4284A | Missense Mutation (SNP) | VAF 90/168 reads (54%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CCDC73 | c.2114T>G p.V705G | Missense Mutation (SNP) | VAF 26/263 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CEACAM21 | c.424+2T>A p.X142_splice | Splice Site (SNP) | VAF 52/309 reads (17%) | called by muse, mutect2, varscan2
- CENPT | c.362C>G p.S121C | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CFAP44 | c.1379A>T p.Q460L | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- CIP2A | c.1964A>T p.D655V | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CKM | c.251T>A p.V84D | Missense Mutation (SNP) | VAF 75/417 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CMTR1 | c.2069T>C p.V690A | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CNTN5 | c.2560T>C p.Y854H | Missense Mutation (SNP) | VAF 107/265 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COG1 | c.1372A>T p.N458Y | Missense Mutation (SNP) | VAF 11/335 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2
- COL4A4 | c.4893C>G p.F1631L | Missense Mutation (SNP) | VAF 156/292 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- COLQ | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 81/353 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- COPE | c.16_27del p.P6_A9del | In Frame Del (DEL) | VAF 53/354 reads (15%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.5662G>A p.A1888T (on ENST00000651564; = p.A1841T on NM_015692.5) | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CRB1 | c.3242A>C p.Y1081S | Missense Mutation (SNP) | VAF 261/916 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- DGKI | c.876G>T p.A292= | Splice Region (SNP) | VAF 45/181 reads (25%) | called by muse, mutect2, varscan2
- DMXL2 | c.2135C>T p.T712I | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ELAVL2 | c.105A>C p.E35D | Missense Mutation (SNP) | VAF 22/534 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- EXOC6B | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- F5 | c.4544T>A p.L1515H | Missense Mutation (SNP) | VAF 34/850 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- FGF12 | c.212A>C p.K71T (on ENST00000454309 / NM_021032.5; = p.K9T on NM_004113.6) | Missense Mutation (SNP) | VAF 89/509 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FOXL1 | c.792C>A p.D264E | Missense Mutation (SNP) | VAF 116/229 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FSIP2 | c.5164G>A p.E1722K | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GDF1 | c.973C>A p.H325N | Missense Mutation (SNP) | VAF 210/437 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GIMAP8 | c.830T>A p.F277Y | Missense Mutation (SNP) | VAF 57/406 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- GUCY2D | c.2031A>C p.R677S | Missense Mutation (SNP) | VAF 19/368 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- HMCN1 | c.7135A>G p.S2379G | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- HMCN1 | c.7136G>T p.S2379I | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HMCN1 | c.7503T>A p.C2501* | Nonsense Mutation (SNP) | VAF 296/752 reads (39%) | called by muse, mutect2, varscan2
- IMPG2 | c.946G>C p.E316Q | Missense Mutation (SNP) | VAF 45/542 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.934); called by muse, mutect2
- IRF2BP1 | c.1563_1564insT p.P522Sfs*58 | Frame Shift Ins (INS) | VAF 50/275 reads (18%) | called by mutect2, pindel, varscan2
- ITGB8 | c.406A>C p.M136L | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITIH1 | c.1532_1538del p.V511Gfs*26 | Frame Shift Del (DEL) | VAF 93/208 reads (45%) | called by mutect2, pindel, varscan2
- KCTD16 | c.942C>G p.S314R | Missense Mutation (SNP) | VAF 46/258 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- KCTD8 | c.666C>G p.D222E | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- KIF1A | c.2267A>G p.D756G | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- KRTAP21-1 | c.113A>T p.Y38F | Missense Mutation (SNP) | VAF 241/402 reads (60%) | SIFT tolerated, low confidence (0.76); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- L3MBTL1 | c.2124-4C>A | Splice Region (SNP) | VAF 40/227 reads (18%) | called by muse, mutect2, varscan2
- L3MBTL3 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.021); called by muse, mutect2
- LHX9 | c.11T>C p.V4A | Missense Mutation (SNP) | VAF 242/619 reads (39%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- MAP3K19 | c.1556A>T p.N519I | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- MBNL3 | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 76/110 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MCCC1 | c.669A>C p.E223D | Missense Mutation (SNP) | VAF 145/581 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- MDN1 | c.9440C>T p.A3147V | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MSH5 | c.2131A>T p.S711C | Missense Mutation (SNP) | VAF 76/466 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- MUC5B | c.10383del p.S3462Afs*29 | Frame Shift Del (DEL) | VAF 211/928 reads (23%) | called by mutect2, varscan2
- NAV3 | c.5749A>G p.K1917E (on ENST00000397909 / NM_001024383.2; = p.K1895E on NM_014903.6) | Missense Mutation (SNP) | VAF 84/310 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- NCAPG2 | c.3381-2A>G p.X1127_splice | Splice Site (SNP) | VAF 70/272 reads (26%) | called by muse, mutect2, varscan2
- NEK5 | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- NLRC5 | c.1276G>C p.G426R | Missense Mutation (SNP) | VAF 109/415 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- NRIP1 | c.527G>C p.R176T | Missense Mutation (SNP) | VAF 184/250 reads (74%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- NSG2 | c.82A>T p.I28F | Missense Mutation (SNP) | VAF 160/333 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- NTNG2 | c.753C>G p.D251E | Missense Mutation (SNP) | VAF 92/520 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- OR52W1 | c.661G>T p.G221C | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- OR6C3 | c.791dup p.A265Gfs*? | Frame Shift Ins (INS) | VAF 71/336 reads (21%) | called by mutect2, pindel, varscan2
- PAK5 | c.1182C>A p.Y394* | Nonsense Mutation (SNP) | VAF 116/337 reads (34%) | called by muse, mutect2, varscan2
- PAX2 | c.197G>A p.S66N | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- PCDH7 | c.2310G>C p.Q770H | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PCDH9 | c.1521G>T p.Q507H | Missense Mutation (SNP) | VAF 83/159 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- PCDHA11 | c.1452G>T p.Q484H | Missense Mutation (SNP) | VAF 384/750 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.078); called by mutect2, varscan2
- PDE5A | c.594G>C p.K198N | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, varscan2
- PDE5A | c.518T>C p.F173S | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, varscan2
- PEX6 | c.1216C>G p.H406D | Missense Mutation (SNP) | VAF 141/704 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- PLAAT1 | c.417_453del p.Y139* (on ENST00000650797; = p.Y34* on NM_020386.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 76/474 reads (16%) | called by mutect2, pindel
- POTEJ | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 93/768 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PRKD2 | c.656del p.A219Vfs*4 | Frame Shift Del (DEL) | VAF 83/570 reads (15%) | called by mutect2, pindel, varscan2
- PRSS36 | c.1421G>T p.C474F | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RABGEF1 | c.1232G>T p.S411I (on ENST00000439720 / NM_001287061.2; = p.S398I on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/571 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RACGAP1 | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RTN3 | c.1903T>G p.L635V (on ENST00000377819 / NM_001265589.2; = p.L616V on NM_201428.3) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- RYR2 | c.6080G>C p.G2027A | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SEC23A | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 91/413 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SENP6 | c.290_296del p.S97Kfs*3 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | called by mutect2, pindel, varscan2
- SHTN1 | c.1721A>G p.K574R | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.049); called by muse, mutect2
- SLC1A7 | c.1482G>T p.E494D | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A10 | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, varscan2
- TACC2 | c.5700-1G>A p.X1900_splice | Splice Site (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- TAS2R16 | c.241T>A p.L81I | Missense Mutation (SNP) | VAF 52/172 reads (30%) | SIFT tolerated (0.46); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TGM2 | c.1366T>A p.F456I | Missense Mutation (SNP) | VAF 79/412 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- TOR1AIP1 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 74/475 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- TSNAX | c.603G>A p.M201I | Missense Mutation (SNP) | VAF 63/458 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- UBE4A | c.989T>G p.L330R (on ENST00000252108 / NM_001204077.2; = p.L337R on NM_004788.4) | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- USP47 | c.1397T>C p.L466P (on ENST00000399455 / NM_001372095.1; = p.L378P on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 130/300 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- XIRP2 | c.6423G>C p.L2141F (on ENST00000628543; = p.L2316F on NM_152381.6) | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- XPR1 | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 30/322 reads (9%) | SIFT tolerated (0.74); PolyPhen benign (0.027); called by muse, mutect2
- ZAN | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 174/1196 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ZBTB24 | c.1754C>G p.T585S | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.001); called by muse, mutect2
- ZBTB38 | c.3209A>G p.Y1070C | Missense Mutation (SNP) | VAF 137/379 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ZFYVE28 | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 87/311 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZIC4 | c.313G>C p.V105L | Missense Mutation (SNP) | VAF 96/683 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF138 | c.740G>C p.G247A (on ENST00000307355 / NM_001367572.1; = p.G221A on NM_006524.4) | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- ZNF267 | c.1030C>G p.P344A | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF292 | c.1845del p.T616Qfs*20 | Frame Shift Del (DEL) | VAF 39/257 reads (15%) | called by mutect2, pindel, varscan2
- ZNF33B | c.1195G>T p.A399S | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ZNF418 | c.889C>T p.H297Y | Missense Mutation (SNP) | VAF 52/334 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.313); called by muse, varscan2
- ZNF771 | c.455G>T p.C152F | Missense Mutation (SNP) | VAF 132/473 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSCAN18 | c.1523C>T p.A508V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCA8 | c.4167C>T p.V1389= | Silent (SNP) | VAF 83/381 reads (22%) | called by muse, mutect2, varscan2
- ACCSL | c.1578C>A p.G526= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs751470079, COSV66581052; called by muse, mutect2, varscan2
- ANK2 | c.738C>G p.V246= | Silent (SNP) | VAF 133/470 reads (28%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1335C>A p.I445= | Silent (SNP) | VAF 37/159 reads (23%) | called by muse, mutect2, varscan2
- APH1A | c.36C>T p.V12= | Silent (SNP) | VAF 121/473 reads (26%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.2202C>A p.S734= (on ENST00000359920 / NM_001130955.2; = p.S630= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/332 reads (13%) | catalogued as rs1300192787, COSV60472660; called by muse, varscan2
- ATP10A | c.1956C>T p.L652= | Silent (SNP) | VAF 160/496 reads (32%) | catalogued as COSV63513284; called by muse, mutect2, varscan2
- BRPF3 | c.495C>T p.D165= | Silent (SNP) | VAF 139/375 reads (37%) | called by muse, mutect2, varscan2
- CDH18 | c.2155A>C p.R719= | Silent (SNP) | VAF 117/369 reads (32%) | called by muse, mutect2, varscan2
- CHST4 | c.564C>T p.Y188= | Silent (SNP) | VAF 251/463 reads (54%) | called by muse, mutect2, varscan2
- CLEC1B | c.243T>C p.C81= | Silent (SNP) | VAF 32/370 reads (9%) | called by muse, mutect2
- CNTNAP2 | c.2124T>A p.V708= | Silent (SNP) | VAF 215/665 reads (32%) | called by muse, mutect2, varscan2
- CSF1 | c.621T>G p.P207= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- DAGLA | c.1416C>T p.S472= | Silent (SNP) | VAF 99/521 reads (19%) | catalogued as rs1189009182, COSV57194264; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.855C>T p.S285= | Silent (SNP) | VAF 63/474 reads (13%) | catalogued as rs370586413; called by muse, mutect2, varscan2
- EFCAB5 | c.123A>G p.P41= | Silent (SNP) | VAF 79/217 reads (36%) | called by muse, mutect2, varscan2
- EPC1 | c.1530C>T p.F510= | Silent (SNP) | VAF 146/272 reads (54%) | called by muse, mutect2, varscan2
- FAT4 | c.7260C>T p.I2420= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as rs754063392; called by muse, mutect2, varscan2
- FCGR3B | c.501C>T p.S167= | Silent (SNP) | VAF 124/505 reads (25%) | catalogued as rs372871192; called by muse, mutect2, varscan2
- FFAR3 | c.708C>G p.V236= | Silent (SNP) | VAF 200/1360 reads (15%) | called by muse, mutect2, varscan2
- GRM3 | c.1014G>A p.Q338= | Silent (SNP) | VAF 88/302 reads (29%) | called by muse, mutect2, varscan2
- HAVCR2 | c.45G>A p.L15= | Silent (SNP) | VAF 55/145 reads (38%) | catalogued as rs1384629793, COSV100324869, COSV57152920; called by muse, varscan2
- HMCES | c.972C>G p.L324= | Silent (SNP) | VAF 90/724 reads (12%) | called by muse, mutect2, varscan2
- HSF5 | c.360G>A p.Q120= | Silent (SNP) | VAF 142/709 reads (20%) | called by muse, mutect2, varscan2
- IVNS1ABP | c.1875C>G p.V625= | Silent (SNP) | VAF 181/453 reads (40%) | called by muse, mutect2, varscan2
- KIAA0930 | c.54C>G p.V18= | Silent (SNP) | VAF 77/353 reads (22%) | called by muse, mutect2, varscan2
- KLHL11 | c.1080G>T p.V360= | Silent (SNP) | VAF 102/311 reads (33%) | called by muse, mutect2, varscan2
- KMT2B | c.5227C>T p.L1743= | Silent (SNP) | VAF 105/622 reads (17%) | called by muse, mutect2, varscan2
- LRP1B | c.1780C>T p.L594= | Silent (SNP) | VAF 52/196 reads (27%) | called by muse, mutect2
- LURAP1L | c.279A>G p.L93= | Silent (SNP) | VAF 267/577 reads (46%) | called by muse, mutect2, varscan2
- MAPK7 | c.1071T>A p.P357= | Silent (SNP) | VAF 55/280 reads (20%) | called by muse, mutect2, varscan2
- MDM4 | c.166T>C p.L56= | Silent (SNP) | VAF 19/250 reads (8%) | called by muse, mutect2
- NOTCH4 | c.4242G>A p.A1414= | Silent (SNP) | VAF 74/151 reads (49%) | catalogued as rs923663349; called by muse, mutect2, varscan2
- OR5K4 | c.663C>T p.I221= | Silent (SNP) | VAF 38/450 reads (8%) | catalogued as COSV61584183; called by muse, mutect2
- P4HB | c.573C>T p.D191= | Silent (SNP) | VAF 184/383 reads (48%) | catalogued as rs141223466; called by muse, mutect2, varscan2
- PAPSS1 | c.1347C>G p.L449= | Silent (SNP) | VAF 32/135 reads (24%) | called by muse, mutect2, varscan2
- PCNX2 | c.6012C>T p.T2004= | Silent (SNP) | VAF 41/232 reads (18%) | catalogued as rs1280768310, COSV50780828; called by muse, mutect2, varscan2
- PEX2 | c.426G>C p.V142= | Silent (SNP) | VAF 94/334 reads (28%) | called by muse, mutect2, varscan2
- PHF20L1 | c.2985A>G p.K995= | Silent (SNP) | VAF 71/374 reads (19%) | called by muse, mutect2, varscan2
- PIGK | c.1114C>T p.L372= | Silent (SNP) | VAF 127/262 reads (48%) | catalogued as rs770833921, COSV63650418; called by muse, mutect2, varscan2
- PLEC | c.2481G>C p.R827= (on ENST00000322810 / NM_201380.4; = p.R717= on NM_000445.5) | Silent (SNP) | VAF 207/716 reads (29%) | called by muse, mutect2, varscan2
- PNRC1 | c.651A>G p.K217= | Silent (SNP) | VAF 44/268 reads (16%) | catalogued as COSV100259712; called by muse, mutect2, varscan2
- PROM1 | c.1239T>A p.V413= | Silent (SNP) | VAF 21/110 reads (19%) | called by muse, mutect2, varscan2
- RER1 | c.453G>T p.V151= | Silent (SNP) | VAF 205/416 reads (49%) | called by muse, mutect2, varscan2
- RHBDL2 | c.564A>G p.G188= | Silent (SNP) | VAF 33/164 reads (20%) | called by muse, mutect2, varscan2
- RSAD1 | c.1041C>A p.G347= | Silent (SNP) | VAF 10/226 reads (4%) | called by muse, mutect2
- SCEL | c.1746G>A p.R582= (on ENST00000349847 / NM_144777.3; = p.R562= on NM_003843.4) | Silent (SNP) | VAF 30/233 reads (13%) | called by muse, mutect2, varscan2
- SETD1B | c.921C>T p.T307= | Silent (SNP) | VAF 165/477 reads (35%) | catalogued as COSV99930387; called by muse, mutect2, varscan2
- SLC9C1 | c.420A>G p.L140= | Silent (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- SLFN11 | c.1446G>A p.E482= | Silent (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2
- SMG5 | c.2637C>T p.R879= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs1057080536; called by muse, mutect2
- SMURF1 | c.2025C>G p.A675= | Silent (SNP) | VAF 221/795 reads (28%) | called by muse, mutect2, varscan2
- SORL1 | c.5037C>T p.T1679= | Silent (SNP) | VAF 57/275 reads (21%) | catalogued as rs201589150; called by muse, mutect2, varscan2
- SVEP1 | c.3714G>A p.L1238= | Silent (SNP) | VAF 25/173 reads (14%) | called by muse, mutect2, varscan2
- TBX15 | c.1647C>T p.N549= (on ENST00000369429 / NM_001330677.2; = p.N443= on NM_152380.3) | Silent (SNP) | VAF 187/307 reads (61%) | catalogued as COSV52874650, COSV99253681; called by muse, mutect2, varscan2
- TP53TG5 | c.502T>C p.L168= | Silent (SNP) | VAF 247/464 reads (53%) | called by muse, mutect2, varscan2
- TRO | c.150G>C p.A50= | Silent (SNP) | VAF 54/218 reads (25%) | called by muse, mutect2, varscan2
- TXNIP | c.1089C>A p.I363= | Silent (SNP) | VAF 100/415 reads (24%) | called by muse, mutect2, varscan2
- URI1 | c.1161G>T p.T387= | Silent (SNP) | VAF 17/130 reads (13%) | catalogued as rs200788387, COSV56352725; called by muse, mutect2, varscan2
- USP49 | c.1113G>A p.G371= | Silent (SNP) | VAF 37/200 reads (19%) | called by muse, mutect2, varscan2
- VASP | c.627T>A p.P209= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- VOPP1 | c.87C>T p.F29= | Silent (SNP) | VAF 49/215 reads (23%) | catalogued as rs1288210503, COSV53387090; called by muse, mutect2, varscan2
- WDR35 | c.357C>T p.R119= | Silent (SNP) | VAF 58/415 reads (14%) | called by muse, mutect2, varscan2
- WNK2 | c.6285T>A p.P2095= (on ENST00000297954 / NM_001282394.1; = p.P2058= on NM_006648.3) | Silent (SNP) | VAF 37/215 reads (17%) | called by muse, mutect2, varscan2
- ZCCHC3 | c.450C>T p.L150= | Silent (SNP) | VAF 51/158 reads (32%) | called by muse, mutect2, varscan2
- ZFAT | c.384G>T p.T128= | Silent (SNP) | VAF 112/353 reads (32%) | catalogued as COSV64734468; called by muse, mutect2, varscan2
- ZNF155 | c.177C>T p.F59= | Silent (SNP) | VAF 85/198 reads (43%) | called by muse, mutect2, varscan2
- ZNF318 | c.6519T>C p.V2173= | Silent (SNP) | VAF 42/266 reads (16%) | called by muse, mutect2, varscan2
- ABCC6P1 | n.1015A>C | RNA (SNP) | VAF 94/761 reads (12%) | called by muse, mutect2, varscan2
- AC024940.1 | n.2135A>T | RNA (SNP) | VAF 39/96 reads (41%) | called by muse, mutect2, varscan2
- AMHR2 | c.1288+42dup | Intron (INS) | VAF 94/332 reads (28%) | catalogued as rs762958910; called by mutect2, varscan2
- ANKRD53 | c.904-485C>T | Intron (SNP) | VAF 85/209 reads (41%) | catalogued as COSV99721339; called by muse, mutect2, varscan2
- ATP6V0D1 | c.302+1274G>T | Intron (SNP) | VAF 127/230 reads (55%) | called by muse, mutect2, varscan2
- ATRNL1 | c.-202C>T | 5'UTR (SNP) | VAF 57/292 reads (20%) | called by muse, mutect2, varscan2
- BBS1 | c.831-315T>G | Intron (SNP) | VAF 90/220 reads (41%) | called by muse, mutect2, varscan2
- BOD1P2 | n.113C>T | RNA (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- C1QTNF1 | c.-14-27C>A | Intron (SNP) | VAF 120/579 reads (21%) | catalogued as COSV59262037, COSV59262781; called by muse, mutect2, varscan2
- CDKN1B | c.*124A>G | 3'UTR (SNP) | VAF 40/141 reads (28%) | catalogued as rs747013464; called by muse, mutect2, varscan2
- DCHS2 | n.5301A>G | RNA (SNP) | VAF 121/235 reads (51%) | called by muse, mutect2, varscan2
- DHX30 | c.125-2348G>T | Intron (SNP) | VAF 92/167 reads (55%) | called by muse, mutect2, varscan2
- ECE1 | c.52-73G>C | Intron (SNP) | VAF 67/121 reads (55%) | catalogued as rs1478705811; called by muse, mutect2, varscan2
- EGFEM1P | n.619T>C | RNA (SNP) | VAF 80/419 reads (19%) | called by muse, mutect2, varscan2
- EIF2B5 | c.2131-27G>C | Intron (SNP) | VAF 116/1046 reads (11%) | called by muse, mutect2, varscan2
- FLNA | c.-29A>T | 5'UTR (SNP) | VAF 139/218 reads (64%) | called by muse, mutect2, varscan2
- GANAB | c.560+451C>T | Intron (SNP) | VAF 55/200 reads (28%) | catalogued as rs182247032, COSV100648171; called by muse, mutect2, varscan2
- GDAP1 | c.*827G>A | 3'UTR (SNP) | VAF 119/467 reads (25%) | called by muse, mutect2
- GPRC5A | c.*3347G>A | 3'UTR (SNP) | VAF 46/195 reads (24%) | catalogued as COSV50008462; called by muse, mutect2, varscan2
- IWS1 | c.-178C>T | 5'UTR (SNP) | VAF 134/427 reads (31%) | catalogued as rs1291769371; called by muse, mutect2, varscan2
- LPIN2 | c.289-42G>T | Intron (SNP) | VAF 70/178 reads (39%) | catalogued as rs375298800; called by muse, mutect2, varscan2
- MINDY4B | chr3:150907443 A>C | 5'Flank (SNP) | VAF 368/633 reads (58%) | called by muse, mutect2, varscan2
- MPG | c.-200A>G | 5'UTR (SNP) | VAF 41/191 reads (21%) | called by muse, mutect2, varscan2
- NPIPB1P | n.868G>A | RNA (SNP) | VAF 248/853 reads (29%) | called by muse, varscan2
- PKD1L2 | n.898G>T | RNA (SNP) | VAF 12/31 reads (39%) | called by muse, mutect2, varscan2
- PKM | c.*63C>T | 3'UTR (SNP) | VAF 59/501 reads (12%) | called by muse, mutect2, varscan2
- PLXND1 | c.*750A>G | 3'UTR (SNP) | VAF 16/94 reads (17%) | called by muse, mutect2, varscan2
- PPP1R13L | c.1355-26C>A | Intron (SNP) | VAF 92/750 reads (12%) | called by muse, mutect2, varscan2
- PPP6C | c.75+34T>A | Intron (SNP) | VAF 138/318 reads (43%) | called by muse, varscan2
- RPS4XP21 | n.522C>A | RNA (SNP) | VAF 89/490 reads (18%) | called by muse, mutect2, varscan2
- SMIM22 | n.429C>T | RNA (SNP) | VAF 49/239 reads (21%) | called by muse, mutect2, varscan2
- SSH2 | c.107+32726A>G | Intron (SNP) | VAF 95/466 reads (20%) | catalogued as rs1391540472; called by muse, mutect2, varscan2
- SSPOP | n.12690C>T | RNA (SNP) | VAF 21/132 reads (16%) | catalogued as COSV100947837; called by muse, mutect2, varscan2
- STON2 | c.2784+20G>A | Intron (SNP) | VAF 14/336 reads (4%) | called by muse, mutect2
- USP34 | chr2:61185859 A>G | 3'Flank (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- ZNF749 | c.-2C>G | 5'UTR (SNP) | VAF 37/453 reads (8%) | called by muse, mutect2
